Somatic mutation profile of tumor specimen TARGET-20-PANLXM-04A (aliquot TARGET-20-PANLXM-04A-01D) from TARGET case TARGET-20-PANLXM, project TARGET-AML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 10.3 years (3,748 days).
Specimen TARGET-20-PANLXM-04A: Sample type: Recurrent Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Bone Marrow NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3e02170-b88c-4a47-b51f-5e216a841e72.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TARGET-20-PANLXM-14A (Bone Marrow Normal), aliquot TARGET-20-PANLXM-14A-01D; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2bf4e9ac-f9d1-4971-9b38-e0a688a9b419

The open-access MAF lists 4 somatic variants for this specimen: 3 protein-altering or splice-affecting, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: 3'UTR 1, Splice Site 1, Frame Shift Del 1, Missense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 30/180 reads (17%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- WT1 | c.1296_1303+3del p.X432_splice | Splice Site (DEL) | VAF 34/108 reads (31%) | called by mutect2, pindel, varscan2
- WT1 | c.1098_1101delinsCT p.V367Sfs*5 | Frame Shift Del (DEL) | VAF 48/147 reads (33%) | called by pindel, varscan2*
- MEIS1 | c.*573T>G | 3'UTR (SNP) | VAF 28/191 reads (15%) | called by muse, mutect2, varscan2
